Somatic mutation profile of tumor specimen TARGET-20-PASFNP-09A (aliquot TARGET-20-PASFNP-09A-01D) from TARGET case TARGET-20-PASFNP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,935 days).
Specimen TARGET-20-PASFNP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfcaf43b-e689-4dc3-88d0-2a10fa5df917.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFNP-14A (Bone Marrow Normal), aliquot TARGET-20-PASFNP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/822b6a7f-4907-44ff-80ef-75e18c31baf8

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.87+1del p.X29_splice | Splice Site (DEL) | VAF 28/173 reads (16%) | catalogued as COSV57444445; called by mutect2, pindel, varscan2
- PCDH9 | c.*1189C>T | 3'UTR (SNP) | VAF 38/402 reads (9%) | called by muse, mutect2
